Somatic mutation profile of tumor specimen TCGA-DF-A2KU-01A (aliquot TCGA-DF-A2KU-01A-11D-A17W-09) from TCGA case TCGA-DF-A2KU, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3.
Specimen TCGA-DF-A2KU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15fa338e-2019-496c-be03-e3ff89123bbb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DF-A2KU-10A (Blood Derived Normal), aliquot TCGA-DF-A2KU-10A-01D-A17W-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/11b46b47-6409-4e21-96dc-6ba3bac52ea6

The open-access MAF lists 12,381 somatic variants for this specimen: 8,979 protein-altering or splice-affecting, 3,120 silent, 282 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8,014, Silent 3,120, Nonsense Mutation 668, Splice Site 180, Intron 113, RNA 76, Splice Region 58, 3'UTR 36, Frame Shift Ins 31, 5'UTR 20, 3'Flank 20, Frame Shift Del 20.

Variants (750 of 12,381; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.3212C>T p.S1071L | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs61750065, CM990038, COSV64672644; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.3544C>T p.R1182W | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as rs797045209, CM073983, COSV100216835; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC011462.1 | c.1045C>T p.R349W | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs373336888; ClinVar: likely pathogenic; called by mutect2, varscan2
- APC | c.562C>T p.Q188* | Nonsense Mutation (SNP) | VAF 24/63 reads (38%) | catalogued as rs869312753, CM023005; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.6709C>T p.R2237* | Nonsense Mutation (SNP) | VAF 13/33 reads (39%) | catalogued as rs768922431, CM130062, COSV57327470; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARMC9 | c.1559C>T p.P520L | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as rs1114167449; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARSB | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.114); catalogued as rs991104525, CM940116, COSV53730185; ClinVar: pathogenic; called by muse, varscan2
- ATM | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 15/48 reads (31%) | catalogued as rs746235533, CM024724, COSV53733622; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATM | c.7220C>A p.S2407* | Nonsense Mutation (SNP) | VAF 26/50 reads (52%) | catalogued as rs1555122149, COSV53772021; ClinVar: pathogenic; called by muse, varscan2
- ATP6V0A4 | c.2420G>A p.R807Q | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs28939081, CM023023; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP7B | c.3818C>T p.P1273L | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758355520, CM061645, CM960134; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BBS5 | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 30/77 reads (39%) | catalogued as rs772757329, CM159212, COSV54752399; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BCL10 | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | catalogued as rs121918314, COSV65353611; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CFAP20 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 32/79 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs753911484, COSV52630441; called by muse, mutect2, varscan2
- CLN3 | c.929G>A p.R310H (on ENST00000360019 / NM_001286104.2; = p.R334H on NM_000086.2) | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs386833695, CM970337; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- COL1A1 | c.1777G>A p.G593S | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs66527965, CM910082, CM920201; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL5A1 | c.2034+1G>A p.X678_splice | Splice Site (SNP) | VAF 20/67 reads (30%) | catalogued as rs886042173, COSV65670134; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL7A1 | c.7411C>T p.R2471* | Nonsense Mutation (SNP) | VAF 29/79 reads (37%) | catalogued as rs121912852, CM960412, COSV60394853; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTNNA2 | c.2788C>T p.R930* (on ENST00000402739 / NM_001282597.3; = p.R882* on NM_004389.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/21 reads (48%) | catalogued as rs760139097, COSV58133839, COSV58164977; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DMD | c.4071+1G>A p.X1357_splice | Splice Site (SNP) | VAF 14/32 reads (44%) | catalogued as rs1060502643, CS084658, CS098754, CS098755; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNMT1 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 15/38 reads (39%) | hotspot (GDC flag); SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as rs751093624, COSV61576638; called by muse, mutect2, varscan2
- DSP | c.313C>T p.R105* | Nonsense Mutation (SNP) | VAF 39/83 reads (47%) | catalogued as rs1435125402, COSV65794239; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EFEMP1 | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as rs121434491, CM990504, COSV62615573; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EIF2B2 | c.922G>A p.V308M | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as rs372548739, CM152520, COSV56720257; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ELMO2 | c.1065+1G>A p.X355_splice | Splice Site (SNP) | VAF 8/37 reads (22%) | catalogued as rs768410753, COSV51685463; ClinVar: pathogenic; called by muse, varscan2
- EP300 | c.4585C>T p.R1529* | Nonsense Mutation (SNP) | VAF 12/45 reads (27%) | catalogued as rs1569118537, CM162047, COSV54325565; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EZH2 | c.2218G>A p.E740K (on ENST00000460911 / NM_001203247.2; = p.E745K on NM_004456.5) | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs397515548, CM1110546, COSV57447594, COSV57464742; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.7540G>A p.G2514R | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs363811, CM025900, CM077253, COSV57326105; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- FGA | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909606, CM100506, CM930249, COSV57393361; ClinVar: pathogenic; called by muse, varscan2
- GLA | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.747); catalogued as rs869312150, CM160443; ClinVar: drug response / likely pathogenic; called by muse, mutect2, varscan2
- GNAL | c.733C>T p.R245* (on ENST00000269162 / NM_001142339.3; = p.R322* on NM_182978.4) | Nonsense Mutation (SNP) | VAF 34/73 reads (47%) | catalogued as rs1252185897, CM135135, COSV52323513; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HUWE1 | c.12559C>T p.R4187C | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs121918527, CM081661, COSV99470874; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ITGB4 | c.3793+1G>A p.X1265_splice | Splice Site (SNP) | VAF 21/49 reads (43%) | catalogued as rs147222357, CS971778; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.3820G>T p.E1274* | Nonsense Mutation (SNP) | VAF 18/44 reads (41%) | catalogued as rs587779294, COSV52288158; ClinVar: likely pathogenic; called by muse, varscan2
- NAA15 | c.1477C>T p.Q493* | Nonsense Mutation (SNP) | VAF 23/58 reads (40%) | catalogued as rs1560973974, COSV56720985; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NHEJ1 | c.532C>T p.R178* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as rs118204453, CM067705; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NSD1 | c.6013C>T p.R2005* | Nonsense Mutation (SNP) | VAF 18/33 reads (55%) | catalogued as rs587784173, CM032979, CM1513402, COSV61772702; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OTC | c.484G>A p.G162R | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs66626662, CM063002, CM920536; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PBRM1 | c.2128C>T p.R710* | Nonsense Mutation (SNP) | VAF 25/57 reads (44%) | hotspot (GDC flag); catalogued as COSV56260264, COSV56262552; called by muse, mutect2, varscan2
- PCDH15 | c.7C>T p.R3* | Nonsense Mutation (SNP) | VAF 7/18 reads (39%) | catalogued as rs137853001, CM012633, COSV57282024; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 13/45 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 25/56 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.285); catalogued as rs1064793732, CM126690, COSV55881636, COSV55977337; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PKD2 | c.1390C>T p.R464* | Nonsense Mutation (SNP) | VAF 20/89 reads (22%) | catalogued as rs121918042, CM971198, COSV52939698; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PLCE1 | c.6448C>T p.R2150* | Nonsense Mutation (SNP) | VAF 22/67 reads (33%) | catalogued as rs267606953, CM104675, COSV53376898; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PMS2 | c.631C>T p.R211* | Nonsense Mutation (SNP) | VAF 25/60 reads (42%) | catalogued as rs760228510, COSV56221873, COSV56224439; ClinVar: pathogenic; called by muse, mutect2, varscan2
- POLE | c.1231G>T p.V411L | Missense Mutation (SNP) | VAF 22/62 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519945, COSV57676103, COSV57677068, COSV57683938; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 31/78 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- PTPRD | c.1292C>T p.S431L | Missense Mutation (SNP) | VAF 24/63 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); catalogued as rs764400127, COSV61926988, COSV61964410; called by muse, varscan2
- PYCR2 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372781135, CM154024; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RDX | c.1732G>A p.D578N | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs121918379, CM071969; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RYR2 | c.7025G>A p.G2342E | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs794728751; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SLC26A2 | c.2144C>T p.A715V | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104893918, CM960501; ClinVar: pathogenic / uncertain significance; called by muse, varscan2
- SLC4A1 | c.1030C>T p.R344* | Nonsense Mutation (SNP) | VAF 22/69 reads (32%) | catalogued as rs750930293, CM1212125, COSV52258614; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMAD2 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 21/66 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV50994862; called by muse, mutect2, varscan2
- SRD5A3 | c.424C>T p.R142* | Nonsense Mutation (SNP) | VAF 44/123 reads (36%) | catalogued as rs267607095, CM104689, COSV51711521; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SZT2 | c.73C>T p.R25* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as rs397515489, CM138628; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TBX5 | c.668C>T p.T223M | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555225344, CM031751, COSV100092545; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TGFB2 | c.391C>T p.R131* | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | catalogued as rs869025531, CM1210056, COSV65109013, COSV65110174; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 15/44 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs1555526131, COSV52674926, COSV52693942, COSV52759722; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USH1C | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 14/50 reads (28%) | catalogued as rs377145777, CM074628; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.2557C>T p.R853W | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs769180200; called by muse, varscan2
- A2ML1 | c.765G>T p.Q255H | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1422425038, COSV55287865; called by muse, mutect2, varscan2
- AASS | c.2036G>A p.G679D | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.897); catalogued as COSV62790722; called by muse, mutect2, varscan2
- ABCA1 | c.2461C>T p.L821F | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as rs1191277071; called by muse, mutect2, varscan2
- ABCA10 | c.2288G>A p.R763H | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.468); catalogued as rs1369621882; called by muse, mutect2, varscan2
- ABCA10 | c.871G>T p.D291Y | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs770989783, COSV99289449; called by muse, mutect2
- ABCA12 | c.5404G>T p.A1802S (on ENST00000272895 / NM_173076.3; = p.A1484S on NM_015657.3) | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0.056); catalogued as COSV55977326; called by muse, mutect2, varscan2
- ABCA12 | c.4033G>A p.G1345R (on ENST00000272895 / NM_173076.3; = p.G1027R on NM_015657.3) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745333434, COSV55949543, COSV55974018; called by muse, mutect2, varscan2
- ABCA12 | c.2378C>T p.A793V (on ENST00000272895 / NM_173076.3; = p.A475V on NM_015657.3) | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.344); catalogued as COSV99792033; called by muse, mutect2, varscan2
- ABCA13 | c.6880G>T p.D2294Y | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.409); catalogued as COSV70034370; called by muse, mutect2
- ABCA13 | c.11794G>A p.V3932I | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.107); catalogued as rs201412160; called by muse, mutect2, varscan2
- ABCA5 | c.4766-1G>T p.X1589_splice | Splice Site (SNP) | VAF 21/59 reads (36%) | catalogued as COSV52230929; called by muse, mutect2, varscan2
- ABCA7 | c.4853C>T p.A1618V | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.775); catalogued as rs1465350182; called by muse, mutect2, varscan2
- ABCA7 | c.5143C>T p.R1715C | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs749753167, CM157244; called by muse, mutect2, varscan2
- ABCA8 | c.778C>A p.L260I | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs372117339; called by muse, mutect2, varscan2
- ABCA9 | c.182C>A p.S61Y | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as rs745956567; called by muse, mutect2, varscan2
- ABCB1 | c.3475G>A p.E1159K | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.045); catalogued as rs781320202, COSV55964374; called by muse, mutect2, varscan2
- ABCB1 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.183); catalogued as rs758755760; called by muse, mutect2, varscan2
- ABCB5 | c.499A>G p.M167V | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs1562534077; called by muse, mutect2, varscan2
- ABCC1 | c.2332C>A p.L778M | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100579311; called by muse, mutect2, varscan2
- ABCC11 | c.2279C>T p.A760V | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as rs1192378299, COSV100750419; called by muse, mutect2, varscan2
- ABCC4 | c.475G>A p.V159I | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.085); catalogued as rs745785051; called by muse, mutect2, varscan2
- ABCC8 | c.800G>A p.C267Y | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV100217708; called by muse, mutect2, varscan2
- ABCC8 | c.396C>A p.F132L | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.616); catalogued as COSV56850338; called by muse, mutect2, varscan2
- ABCC9 | c.4067C>A p.S1356Y | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV53984544; called by muse, mutect2
- ABCD1 | c.362G>A p.C121Y | Missense Mutation (SNP) | VAF 61/150 reads (41%) | SIFT tolerated (0.97); PolyPhen benign (0.021); catalogued as COSV54383795; called by muse, mutect2, varscan2
- ABCD1 | c.2065C>T p.R689C | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs782376163; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCD3 | c.665C>T p.T222M | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs747106886, COSV59866185; called by muse, mutect2, varscan2
- ABCD4 | c.1735C>T p.R579W | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780481912; called by muse, mutect2, varscan2
- ABCF3 | c.1559G>A p.R520H | Missense Mutation (SNP) | VAF 70/210 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1301386278, COSV53054426; called by muse, mutect2, varscan2
- ABCG2 | c.1957A>G p.K653E | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372911459; called by muse, mutect2, varscan2
- ABCG2 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs1160489451; called by muse, mutect2, varscan2
- ABHD16B | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.543); catalogued as rs1401383549; called by muse, mutect2, varscan2
- ABHD17A | c.892C>T p.R298C (on ENST00000292577 / NM_001130111.2; = p.R349C on NM_031213.4) | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.701); catalogued as rs762734277; called by muse, varscan2
- ABHD17A | c.505G>A p.A169T (on ENST00000292577 / NM_001130111.2; = p.A220T on NM_031213.4) | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); catalogued as rs7249021, COSV51750112; called by muse, mutect2, varscan2
- ABI1 | c.1357G>A p.A453T | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as COSV100697997, COSV61015898; called by muse, mutect2, varscan2
- ABI1 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.27); catalogued as rs202085454; called by muse, mutect2, varscan2
- ABL1 | c.3299G>A p.C1100Y | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV59340408; called by muse, mutect2, varscan2
- ABLIM2 | c.1465G>A p.G489R (on ENST00000341937 / NM_001130084.2; = p.G438R on NM_032432.5) | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs780756394; called by muse, mutect2, varscan2
- ABO | c.666G>T p.E222D | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101505931; called by muse, mutect2, varscan2
- AC008676.3 | c.319G>A p.V107I | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.022); catalogued as rs1561747866; called by muse, mutect2, varscan2
- AC008676.3 | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 35/96 reads (36%) | catalogued as rs1290797080, COSV56637203; called by muse, mutect2, varscan2
- AC011462.1 | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.039); catalogued as rs373555514, COSV54198168; called by muse, mutect2, varscan2
- AC092143.1 | c.2105A>T p.D702V | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV59247410; called by muse, mutect2, varscan2
- AC093155.3 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs753328703; called by muse, varscan2
- AC093525.2 | c.1024C>T p.H342Y | Missense Mutation (SNP) | VAF 19/68 reads (28%) | PolyPhen benign (0.319); catalogued as rs749034390, COSV99036677; called by muse, mutect2, varscan2
- ACACA | c.5941C>T p.P1981S | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.597); catalogued as rs1417700554; called by muse, mutect2, varscan2
- ACACB | c.3301C>T p.R1101* | Nonsense Mutation (SNP) | VAF 21/78 reads (27%) | catalogued as rs757945449; called by muse, mutect2, varscan2
- ACACB | c.6985C>T p.R2329C | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs560469698; called by muse, mutect2, varscan2
- ACADSB | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.584); catalogued as rs745481903, COSV62551017; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACKR3 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1559473742, COSV56023116; called by muse, mutect2, varscan2
- ACKR4 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs749074078; called by muse, mutect2, varscan2
- ACOT7 | c.326G>A p.R109H (on ENST00000377855 / NM_181864.3; = p.R99H on NM_007274.4) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs373748213; called by muse, mutect2, varscan2
- ACOT9 | c.816G>A p.K272= | Splice Region (SNP) | VAF 29/92 reads (32%) | catalogued as rs763233076; called by muse, mutect2, varscan2
- ACOX2 | c.1942C>T p.R648C | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs756752270, COSV57148809; called by muse, mutect2, varscan2
- ACOX3 | c.1306C>T p.R436W | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs146052311; called by muse, mutect2, varscan2
- ACP5 | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs369579418; called by muse, mutect2, varscan2
- ACSBG1 | c.1405C>T p.R469C | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as rs772359349, COSV51906138; called by muse, mutect2, varscan2
- ACSBG2 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.051); catalogued as rs372123644; called by muse, mutect2, varscan2
- ACSL1 | c.2045G>A p.R682Q | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs183356632, COSV99860619; called by muse, mutect2, varscan2
- ACSL1 | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs751319076; called by muse, varscan2
- ACSL3 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62485212; called by muse, mutect2, varscan2
- ACSM2A | c.1211C>A p.P404H (on ENST00000219054; = p.P325H on NM_001308169.2) | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as rs201551733; called by muse, mutect2, varscan2
- ACSM3 | c.32G>A p.R11H | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); catalogued as rs756159393, COSV99184047; called by muse, varscan2
- ACSS3 | c.1615G>A p.D539N | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54097335; called by muse, mutect2, varscan2
- ACTN1 | c.1019C>T p.T340M | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV51995318; called by muse, mutect2, varscan2
- ACTN4 | c.2651C>T p.A884V | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs767861850; called by muse, mutect2, varscan2
- ACTR1A | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as rs568740960, COSV64023673; called by muse, mutect2, varscan2
- ACTR2 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.174); catalogued as rs746870357; called by muse, mutect2, varscan2
- ACTR3B | c.958G>A p.V320I | Missense Mutation (SNP) | VAF 58/157 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.658); catalogued as rs752433041; called by muse, mutect2, varscan2
- ACVR1 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.158); catalogued as rs373187352, COSV55123705; called by muse, mutect2, varscan2
- ACVRL1 | c.806C>T p.S269L | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101188046; called by muse, mutect2, varscan2
- ADA | c.363-1G>T p.X121_splice | Splice Site (SNP) | VAF 33/101 reads (33%) | catalogued as CS159401; called by muse, varscan2
- ADAD1 | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.804); catalogued as rs546801281, COSV56642389; called by muse, mutect2, varscan2
- ADAM2 | c.207T>A p.N69K | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as rs1313673503; called by muse, mutect2, varscan2
- ADAM23 | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.57); PolyPhen benign (0.04); catalogued as rs779781736; called by muse, mutect2, varscan2
- ADAM23 | c.1528G>A p.V510M | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as rs540276873, COSV100008173; called by muse, mutect2, varscan2
- ADAM29 | c.1819G>A p.D607N | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs766305290, COSV63665781, COSV63666862; called by muse, mutect2, varscan2
- ADAM7 | c.1149G>T p.K383N | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as rs748116709, COSV51545609; called by muse, mutect2, varscan2
- ADAM7 | c.1393G>T p.D465Y | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV51534609; called by muse, varscan2
- ADAMTS2 | c.2548G>T p.E850* | Nonsense Mutation (SNP) | VAF 25/78 reads (32%) | catalogued as COSV52378623; called by muse, mutect2, varscan2
- ADAMTS3 | c.2516T>C p.V839A | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as COSV99712480; called by muse, mutect2, varscan2
- ADAMTS4 | c.1990C>T p.R664C | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs570236275, COSV63490368; called by muse, mutect2, varscan2
- ADAMTS4 | c.1879G>A p.A627T | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as rs1319376302; called by muse, mutect2, varscan2
- ADAMTS5 | c.350G>T p.G117V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.021); catalogued as COSV53177515; called by muse, mutect2, varscan2
- ADAMTS9 | c.3333G>A p.W1111* | Nonsense Mutation (SNP) | VAF 30/78 reads (38%) | catalogued as COSV99900704; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2653G>A p.D885N | Missense Mutation (SNP) | VAF 66/172 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as rs561084765; ClinVar: uncertain significance; called by muse, mutect2
- ADAMTSL3 | c.2426C>T p.S809L | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.478); catalogued as rs370505336; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1409G>A p.R470H | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs137999265; called by muse, mutect2, varscan2
- ADAR | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs187076847; called by muse, mutect2, varscan2
- ADAT2 | c.504G>T p.K168N | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52794261; called by muse, mutect2, varscan2
- ADCY1 | c.3283G>A p.V1095I | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.006); catalogued as rs763670732, COSV52041109; called by muse, mutect2, varscan2
- ADCY4 | c.1993G>A p.A665T | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.66); PolyPhen benign (0.028); catalogued as rs575546823; called by muse, mutect2, varscan2
- ADCY5 | c.3637G>A p.G1213S | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774848359, COSV59197832; called by muse, mutect2, varscan2
- ADCY5 | c.2917G>A p.G973R | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as rs749564195, COSV59200140; called by muse, mutect2, varscan2
- ADCY6 | c.308C>T p.T103M | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as rs746195042, COSV57168003; called by muse, mutect2, varscan2
- ADGRA2 | c.3109G>T p.A1037S | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs547298880; called by muse, mutect2, varscan2
- ADGRA3 | c.2543G>A p.R848Q | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs966886838, COSV51560619; called by muse, mutect2, varscan2
- ADGRA3 | c.2455A>G p.T819A | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as rs759676986; called by muse, mutect2, varscan2
- ADGRB2 | c.1883G>A p.R628Q | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.459); catalogued as rs201601920; called by muse, mutect2, varscan2
- ADGRB3 | c.2753G>A p.C918Y | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53257245; called by muse, mutect2, varscan2
- ADGRB3 | c.4515G>T p.K1505N | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1468313815; called by muse, varscan2
- ADGRB3 | c.4529C>A p.P1510H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53261745; called by muse, varscan2
- ADGRF3 | c.3064C>T p.L1022F (on ENST00000311519 / NM_001145168.1; = p.L823F on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs370350634, COSV100275246; called by muse, mutect2, varscan2
- ADGRF3 | c.998C>T p.A333V (on ENST00000311519 / NM_001145168.1; = p.A134V on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs540093136, COSV100274948; called by muse, mutect2, varscan2
- ADGRF5 | c.2276C>T p.A759V | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs375753155; called by muse, mutect2, varscan2
- ADGRG2 | c.1061C>T p.A354V (on ENST00000379869 / NM_001079858.3; = p.A351V on NM_005756.4) | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1254226753, COSV61339022, COSV61341057; called by muse, mutect2, varscan2
- ADGRG3 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as rs752087259, COSV59651487; called by muse, mutect2, varscan2
- ADGRG4 | c.2288C>T p.T763I | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as rs775190780, COSV99796863; called by muse, mutect2, varscan2
- ADGRG4 | c.3379A>G p.T1127A | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as COSV54968416; called by muse, mutect2, varscan2
- ADGRL1 | c.3164C>T p.A1055V (on ENST00000340736 / NM_001008701.3; = p.A1050V on NM_014921.5) | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.221); catalogued as rs764627786, COSV61567000; called by muse, mutect2, varscan2
- ADGRL1 | c.484G>A p.A162T (on ENST00000340736 / NM_001008701.3; = p.A157T on NM_014921.5) | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs764093428; called by muse, mutect2, varscan2
- ADGRL2 | c.298C>T p.R100* | Nonsense Mutation (SNP) | VAF 12/54 reads (22%) | catalogued as rs775512975, COSV54658637; called by muse, varscan2
- ADGRV1 | c.12917G>A p.S4306N | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.9); PolyPhen benign (0.057); catalogued as rs1053016545; called by muse, mutect2, varscan2
- ADH1C | c.57G>T p.K19N | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs748223863, COSV72463413; called by muse, mutect2, varscan2
- ADH5 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs374481239; called by muse, mutect2, varscan2
- ADHFE1 | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52553834; called by muse, mutect2, varscan2
- ADORA2B | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs1384632847; called by muse, mutect2, varscan2
- ADRA1D | c.1273C>T p.R425W | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as rs971135580; called by muse, mutect2, varscan2
- ADRA2B | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771208116; called by muse, mutect2, varscan2
- AFAP1 | c.1807G>A p.A603T | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs759854298; called by muse, mutect2, varscan2
- AFDN | c.4300C>T p.R1434W | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs772514505; called by muse, varscan2
- AFG3L2 | c.293-1G>A p.X98_splice | Splice Site (SNP) | VAF 22/58 reads (38%) | catalogued as COSV99301913; called by muse, mutect2, varscan2
- AGAP2 | c.1953G>A p.A651= (on ENST00000547588 / NM_001122772.2; = p.A315= on NM_014770.4) | Splice Region (SNP) | VAF 19/57 reads (33%) | catalogued as rs1257645556; called by muse, mutect2, varscan2
- AGAP3 | c.2036G>A p.R679H (on ENST00000622464; = p.R715H on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750679955, COSV68244885; called by muse, mutect2, varscan2
- AGAP4 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 78/231 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.501); catalogued as rs1422901360; called by muse, mutect2, varscan2
- AGER | c.824G>A p.G275D | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs751726848; called by muse, mutect2, varscan2
- AGMO | c.1021G>A p.V341I | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs375360314; called by muse, varscan2
- AGPS | c.1855G>T p.V619L | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV104384329; called by muse, mutect2, varscan2
- AGRN | c.3056C>T p.P1019L | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs756489447, COSV101039177; ClinVar: uncertain significance; called by muse, varscan2
- AGT | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.037); catalogued as COSV64183827; called by muse, mutect2, varscan2
- AGTPBP1 | c.905C>T p.S302L | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.83); catalogued as rs146598781; called by muse, mutect2, varscan2
- AGXT2 | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs200627716; called by muse, mutect2, varscan2
- AGXT2 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs548090207; called by muse, mutect2, varscan2
- AHCYL2 | c.1472G>A p.R491Q | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as rs1045110379, COSV61491449; called by muse, mutect2, varscan2
- AHNAK | c.6694G>A p.V2232M | Missense Mutation (SNP) | VAF 61/172 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs750778666; called by muse, mutect2, varscan2
- AHNAK2 | c.13109C>A p.P4370H | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.039); catalogued as rs1414478550; called by muse, mutect2, varscan2
- AHNAK2 | c.7088C>T p.T2363I | Missense Mutation (SNP) | VAF 64/175 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as rs1251208159; called by muse, mutect2, varscan2
- AHR | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs1298270087; called by muse, varscan2
- AHR | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54121955; called by muse, varscan2
- AHRR | c.1406G>A p.R469Q | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs769781351, COSV57084697, COSV57087025; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AICDA | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); catalogued as rs775067086; called by muse, mutect2, varscan2
- AIPL1 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs1049797491, COSV51507102; called by muse, mutect2, varscan2
- AK5 | c.1504C>T p.R502W (on ENST00000354567 / NM_174858.3; = p.R476W on NM_012093.4) | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as rs765399590, COSV100642366, COSV60982149; called by muse, mutect2, varscan2
- AKAP13 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs115657055; called by muse, mutect2, varscan2
- AKAP13 | c.6463G>A p.V2155I (on ENST00000394518 / NM_007200.5; = p.V2159I on NM_006738.6) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63453519; called by muse, mutect2, varscan2
- AKAP17A | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as rs749621675, COSV100002481; called by muse, mutect2, varscan2
- AKAP17A | c.1294C>T p.R432W | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs754874095; called by muse, mutect2, varscan2
- AKAP3 | c.1700C>T p.A567V | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs758916430; called by muse, varscan2
- AKAP6 | c.6422C>T p.T2141I | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV55219175; called by muse, mutect2, varscan2
- AKAP8 | c.1781C>T p.A594V | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs765576072; called by muse, mutect2, varscan2
- AKAP9 | c.209C>T p.S70F | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as rs765951390, COSV62342500; called by muse, mutect2, varscan2
- AKAP9 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs768097461; called by muse, mutect2, varscan2
- AKNA | c.1913G>A p.R638H | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs578095975, COSV56314528; called by muse, mutect2, varscan2
- AKNAD1 | c.2033G>A p.R678K | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs746409597; called by muse, mutect2, varscan2
- AKR1D1 | c.439C>A p.L147M | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs973431898, COSV54336058; called by muse, mutect2, varscan2
- AKR7A2 | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as rs1458311650; called by muse, mutect2, varscan2
- AL136295.1 | c.1538G>A p.R513H | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.876); catalogued as rs146632278; called by muse, mutect2, varscan2
- AL592490.1 | c.247G>A p.G83S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1422291829; called by muse, mutect2, varscan2
- ALAS1 | c.1169C>T p.A390V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs773336919, COSV59626776; called by mutect2, varscan2
- ALAS2 | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58189668; called by muse, mutect2, varscan2
- ALAS2 | c.46C>T p.R16W | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as rs780949974, COSV100238021; called by muse, mutect2, varscan2
- ALDH1A3 | c.1012G>A p.A338T | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV60902704; called by muse, mutect2, varscan2
- ALDH1L2 | c.2465C>T p.A822V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.943); catalogued as COSV51560423; called by muse, mutect2, varscan2
- ALDH1L2 | c.786+1G>A p.X262_splice | Splice Site (SNP) | VAF 8/18 reads (44%) | catalogued as rs1350404361; called by muse, mutect2, varscan2
- ALDH6A1 | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as rs1162172204; called by muse, mutect2, varscan2
- ALG13 | c.3278C>T p.S1093F | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as rs1465704791; ClinVar: likely benign; called by muse, mutect2, varscan2
- ALG5 | c.267C>A p.S89R | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs745828516; called by muse, mutect2, varscan2
- ALG6 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.618); catalogued as rs756038267; called by muse, mutect2, varscan2
- ALG9 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 8/133 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); catalogued as rs781988506; called by muse, mutect2
- ALK | c.4070C>A p.P1357H | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66591901; called by muse, mutect2, varscan2
- ALKBH2 | c.103G>T p.E35* | Nonsense Mutation (SNP) | VAF 14/48 reads (29%) | catalogued as COSV99655166; called by muse, mutect2, varscan2
- ALOX12 | c.862G>A p.V288M | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as rs758721831, COSV52350990; called by muse, mutect2, varscan2
- ALPK2 | c.5536G>A p.V1846M | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.964); catalogued as rs771616584; called by muse, mutect2, varscan2
- ALS2 | c.3394C>T p.R1132C | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs149670991, COSV51885571; called by muse, mutect2, varscan2
- AMD1 | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs753517621, COSV64387769; called by muse, mutect2, varscan2
- AMER3 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as rs147594621; called by muse, mutect2, varscan2
- AMHR2 | c.853G>A p.G285S | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs778214960; called by muse, mutect2, varscan2
- AMIGO2 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as COSV56973154; called by muse, mutect2, varscan2
- AMIGO3 | c.1402G>A p.V468M | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as rs1559690096; called by muse, mutect2, varscan2
- AMMECR1L | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.2); catalogued as rs773853713, COSV55762122; called by muse, mutect2, varscan2
- AMOTL1 | c.1723C>T p.R575W | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as rs199710090; called by muse, varscan2
- AMOTL2 | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.65); catalogued as rs747545396, COSV99998318; called by muse, mutect2, varscan2
- AMY2A | c.745G>A p.V249I | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as rs755909947; called by muse, mutect2, varscan2
- AMZ2 | c.263G>T p.S88I | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV63083790; called by muse, mutect2, varscan2
- ANAPC1 | c.4619G>A p.R1540H | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1237878656; called by muse, mutect2, varscan2
- ANGEL1 | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs764641496, COSV99200299; called by muse, varscan2
- ANGPTL1 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1228887425, COSV52367044; called by muse, mutect2, varscan2
- ANK1 | c.5123C>T p.S1708L | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.035); catalogued as rs368366417; called by muse, mutect2, varscan2
- ANK1 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.429); catalogued as rs1426323536, COSV99225449; called by muse, mutect2, varscan2
- ANK2 | c.5971C>T p.R1991W | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1442984107, COSV52148543; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK3 | c.7922C>T p.A2641V | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV55083424; called by muse, mutect2, varscan2
- ANK3 | c.2396C>T p.A799V | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99778456; called by muse, mutect2, varscan2
- ANKK1 | c.1955C>A p.P652H | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58274087; called by muse, mutect2, varscan2
- ANKMY1 | c.1525G>A p.D509N | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as rs372240297; called by muse, mutect2, varscan2
- ANKRD11 | c.3931C>T p.R1311* | Nonsense Mutation (SNP) | VAF 20/47 reads (43%) | catalogued as COSV56355766; called by muse, mutect2, varscan2
- ANKRD11 | c.322G>A p.G108S | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1419112752; called by muse, mutect2, varscan2
- ANKRD12 | c.4458G>A p.M1486I | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs1267977279; called by muse, mutect2, varscan2
- ANKRD16 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as rs747391576; called by muse, mutect2, varscan2
- ANKRD17 | c.5984G>A p.R1995Q | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs531067640, COSV58214890; called by muse, mutect2, varscan2
- ANKRD17 | c.1861G>A p.A621T | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs745621090, COSV58225617; called by muse, mutect2, varscan2
- ANKRD2 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs1268138572; called by muse, mutect2, varscan2
- ANKRD20A1 | c.2013C>A p.F671L | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.017); catalogued as rs1381986024; called by mutect2, varscan2
- ANKRD23 | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.946); catalogued as rs1464953007; called by muse, mutect2, varscan2
- ANKRD24 | c.958C>T p.R320* | Nonsense Mutation (SNP) | VAF 20/57 reads (35%) | catalogued as rs779286012, COSV53668828; called by muse, mutect2, varscan2
- ANKRD24 | c.3010C>T p.R1004C | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1337562891, COSV53677013; called by muse, mutect2, varscan2
- ANKRD26 | c.742C>T p.L248F | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as rs753845455, COSV65793542; called by muse, mutect2, varscan2
- ANKRD28 | c.73C>T p.R25* | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as COSV67516849; called by muse, mutect2, varscan2
- ANKRD30A | c.1931C>A p.P644H (on ENST00000611781; = p.P588H on NM_052997.2) | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs199874591; called by muse, mutect2, varscan2
- ANKRD44 | c.1435G>A p.A479T | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs767545068, COSV56563016; called by muse, mutect2, varscan2
- ANKRD50 | c.3857C>T p.A1286V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs778120664; called by muse, mutect2, varscan2
- ANKRD50 | c.3488C>A p.S1163Y | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1359100186; called by muse, mutect2, varscan2
- ANKRD52 | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV99921092; called by muse, mutect2, varscan2
- ANKS1A | c.956C>T p.P319L | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV64458679; called by muse, mutect2, varscan2
- ANKS1A | c.1517C>T p.S506F | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1191588701; called by muse, mutect2, varscan2
- ANKS4B | c.1075G>T p.E359* | Nonsense Mutation (SNP) | VAF 11/33 reads (33%) | catalogued as rs1455093839, COSV100289813; called by muse, mutect2, varscan2
- ANLN | c.1161A>C p.E387D | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV99732037; called by muse, mutect2, varscan2
- ANO8 | c.2705G>A p.R902H | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs771912275; called by muse, varscan2
- ANPEP | c.2378G>A p.R793Q | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs759517288; called by muse, mutect2, varscan2
- ANTXR1 | c.1189C>T p.R397C | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774300710, COSV58013918; called by muse, mutect2, varscan2
- ANXA13 | c.295A>G p.M99V | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.577); catalogued as rs757903621, COSV99146090; called by muse, varscan2
- ANXA4 | c.397C>T p.Q133* | Nonsense Mutation (SNP) | VAF 29/77 reads (38%) | catalogued as rs774777486; called by muse, mutect2, varscan2
- ANXA6 | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs779896564; called by muse, mutect2, varscan2
- AOC3 | c.1909C>T p.R637W | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371131039; called by muse, mutect2, varscan2
- AP001781.2 | c.521G>A p.C174Y | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1388814818; called by muse, mutect2, varscan2
- AP1M2 | c.431C>T p.T144M | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.301); catalogued as rs370107597; called by muse, mutect2, varscan2
- AP2A2 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs763389818, COSV59959497, COSV59960310; called by muse, mutect2, varscan2
- AP2B1 | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99250980; called by muse, mutect2, varscan2
- AP3M1 | c.857G>T p.S286I | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.195); catalogued as COSV100786788; called by muse, mutect2, varscan2
- AP4S1 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs112987601; called by muse, mutect2, varscan2
- AP5M1 | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs866308131; called by muse, mutect2, varscan2
- APAF1 | c.600G>T p.Q200H (on ENST00000551964 / NM_181861.2; = p.Q189H on NM_001160.3) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59663067; called by muse, mutect2, varscan2
- APBA1 | c.1120C>T p.P374S | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1423555549; called by muse, varscan2
- APBA2 | c.1460C>T p.T487M | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as rs150027586; called by muse, mutect2, varscan2
- APBA3 | c.722C>T p.T241M | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.113); catalogued as rs774374922, COSV53661960; called by muse, mutect2, varscan2
- APC2 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.992); catalogued as rs142402932; called by muse, mutect2, varscan2
- APEH | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1019425441, COSV56534537; called by muse, mutect2, varscan2
- APIP | c.659T>C p.I220T | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as rs1565130905; called by muse, mutect2, varscan2
- APLF | c.1325C>T p.T442M | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as rs199832884, COSV58148267; called by muse, mutect2, varscan2
- APLNR | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as rs760732461, COSV57241499; called by muse, mutect2, varscan2
- APLNR | c.364G>A p.G122S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.852); catalogued as rs752254107, COSV57243241; called by mutect2, varscan2
- APLP1 | c.1241G>A p.R414Q | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.421); catalogued as rs1321429015, COSV55706158; called by muse, mutect2, varscan2
- APLP2 | c.1085C>T p.A362V | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1286666764, COSV53841943; called by muse, mutect2, varscan2
- APMAP | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.173); catalogued as rs775710141; called by muse, mutect2, varscan2
- APOB | c.11507C>T p.A3836V | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.03); catalogued as rs1315039387, COSV99267481; called by muse, mutect2, varscan2
- APOB | c.9410T>G p.L3137R | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99265257; called by muse, mutect2, varscan2
- APOB | c.6949G>A p.V2317I | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.94); PolyPhen benign (0.018); catalogued as rs746796545; called by muse, varscan2
- APOB | c.6940C>A p.L2314I | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV104373681; called by muse, varscan2
- APOBEC3D | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.602); catalogued as rs759937585; called by muse, mutect2
- APOBEC3D | c.415C>T p.R139W | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs61752258, COSV53328099; called by muse, mutect2, varscan2
- APOBEC3F | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.761); catalogued as COSV100415254; called by muse, mutect2, varscan2
- APOBEC3H | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 57/127 reads (45%) | catalogued as rs535832435; called by muse, mutect2
- APOH | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); catalogued as rs142075038; called by muse, mutect2, varscan2
- APOO | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs369973145, COSV64870573; called by muse, mutect2, varscan2
- APPL2 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs759583132, COSV99314775; called by muse, mutect2, varscan2
- AQP12A | c.131C>T p.T44M | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs143658178; called by muse, mutect2, varscan2
- AQP12B | c.431G>A p.R144H (on ENST00000621682; = p.R156H on NM_001102467.2) | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs771419765, COSV101315883; called by muse, mutect2, varscan2
- AQP9 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.643); catalogued as COSV99583288; called by muse, mutect2, varscan2
- AQR | c.1600C>T p.R534* | Nonsense Mutation (SNP) | VAF 6/92 reads (7%) | catalogued as rs1006047053; called by muse, mutect2
- ARAP1 | c.2378A>G p.N793S (on ENST00000393609 / NM_001040118.2; = p.N548S on NM_015242.4) | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.141); catalogued as rs201502644; called by muse, mutect2, varscan2
- ARCN1 | c.1276G>A p.D426N | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs781853184; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARF1 | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.932); catalogued as COSV99683409; called by muse, mutect2, varscan2
- ARFGEF1 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs773900413; called by muse, varscan2
- ARFGEF3 | c.1475C>T p.P492L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as rs144367852, COSV52451330; called by muse, varscan2
- ARFGEF3 | c.4541G>A p.R1514Q | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as rs199906287, COSV52450670; called by muse, mutect2, varscan2
- ARFGEF3 | c.5432C>T p.A1811V | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1463417276, COSV52454572; called by muse, mutect2, varscan2
- ARGLU1 | c.128C>A p.S43Y | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV100639742; called by muse, mutect2, varscan2
- ARHGAP17 | c.2545C>T p.R849C (on ENST00000289968 / NM_001006634.3; = p.R771C on NM_018054.6) | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs772552729, COSV51509512; called by muse, mutect2, varscan2
- ARHGAP21 | c.5006C>A p.S1669Y | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as rs1192459581; called by muse, mutect2, varscan2
- ARHGAP26 | c.1877C>T p.S626F | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV50840663; called by muse, mutect2, varscan2
- ARHGAP28 | c.1142C>T p.P381L (on ENST00000383472 / NM_001366230.1; = p.P222L on NM_001010000.3) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369240181; called by muse, varscan2
- ARHGAP30 | c.2188G>A p.E730K | Missense Mutation (SNP) | VAF 62/155 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); catalogued as rs748532451; called by muse, mutect2, varscan2
- ARHGAP30 | c.967C>T p.R323W | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753681564; called by muse, varscan2
- ARHGAP31 | c.3860C>T p.T1287I | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs766647440; called by muse, mutect2, varscan2
- ARHGAP32 | c.6109C>T p.R2037* (on ENST00000310343 / NM_001378025.1; = p.R1688* on NM_014715.4) | Nonsense Mutation (SNP) | VAF 38/108 reads (35%) | catalogued as rs1196647735; called by muse, mutect2, varscan2
- ARHGAP32 | c.5438G>A p.R1813H (on ENST00000310343 / NM_001378025.1; = p.R1464H on NM_014715.4) | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs199633352; called by muse, mutect2, varscan2
- ARHGAP32 | c.4630G>A p.A1544T (on ENST00000310343 / NM_001378025.1; = p.A1195T on NM_014715.4) | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.001); catalogued as rs756000808, COSV59844185; called by muse, mutect2, varscan2
- ARHGAP4 | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT tolerated (0.9); PolyPhen benign (0.013); catalogued as rs1403388551; called by muse, mutect2, varscan2
- ARHGAP44 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52390291; called by muse, mutect2, varscan2
- ARHGAP44 | c.1910C>T p.A637V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs1438282617; called by muse, mutect2, varscan2
- ARHGEF10 | c.3199G>A p.V1067I (on ENST00000398564; = p.V1042I on NM_014629.4) | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as rs758678206, COSV50651494; called by muse, mutect2, varscan2
- ARHGEF10L | c.3509G>A p.G1170D | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1018564979; called by muse, mutect2, varscan2
- ARHGEF11 | c.3100C>T p.R1034C | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59352457; called by muse, mutect2, varscan2
- ARHGEF11 | c.1822C>T p.R608C | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1388884489, CM142294, COSV100168393; called by muse, mutect2, varscan2
- ARHGEF15 | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 12/53 reads (23%) | catalogued as rs908159482, COSV100730198; called by muse, mutect2, varscan2
- ARHGEF15 | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs376034940, COSV62725688; called by muse, mutect2, varscan2
- ARHGEF17 | c.2512G>A p.A838T | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as COSV55229438; called by muse, varscan2
- ARHGEF17 | c.3797G>A p.R1266H | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs747884675; called by muse, varscan2
- ARHGEF2 | c.1082G>A p.R361H (on ENST00000361247 / NM_001162383.2; = p.R333H on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV58114766; called by muse, mutect2, varscan2
- ARHGEF28 | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs557233944, COSV99710089; called by muse, mutect2, varscan2
- ARHGEF28 | c.1123G>A p.A375T | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs759665233; called by muse, mutect2, varscan2
- ARHGEF28 | c.1276G>A p.V426M | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs199889911; called by muse, mutect2, varscan2
- ARHGEF4 | c.877C>A p.L293I | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.05); catalogued as COSV58120804; called by muse, mutect2, varscan2
- ARHGEF40 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs114773484; called by mutect2, varscan2
- ARHGEF5 | c.3677G>A p.R1226Q | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as rs767400012; called by mutect2, varscan2
- ARHGEF6 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.346); catalogued as rs759340844, COSV51687739; called by muse, mutect2, varscan2
- ARHGEF7 | c.2096C>T p.A699V (on ENST00000375741 / NM_001113511.2; = p.A521V on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.025); catalogued as rs1388441567, COSV99521897; called by muse, mutect2, varscan2
- ARHGEF9 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs1556347347; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARID1A | c.4494G>A p.W1498* | Nonsense Mutation (SNP) | VAF 35/80 reads (44%) | catalogued as COSV61375153; called by muse, mutect2, varscan2
- ARID1A | c.5974T>C p.S1992P | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61388720; called by muse, mutect2, varscan2
- ARID2 | c.1447C>T p.P483S | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.197); catalogued as rs374540100; called by muse, mutect2, varscan2
- ARID2 | c.5431C>A p.L1811I | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.531); catalogued as COSV57605993; called by muse, mutect2, varscan2
- ARID4B | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1314403068, COSV51598595; called by muse, mutect2, varscan2
- ARL15 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs762822538, COSV101544756, COSV72291226; called by muse, mutect2, varscan2
- ARMC1 | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.353); catalogued as rs531455993, COSV52533787; called by muse, mutect2, varscan2
- ARMC7 | c.362C>T p.T121M | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs770124022; called by muse, varscan2
- ARMCX2 | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); catalogued as rs781887055, COSV57529506; called by muse, mutect2
- ARMCX5 | c.1545A>C p.E515D | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV55767080; called by muse, mutect2, varscan2
- ARMH3 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs745492483, COSV64233829; called by muse, mutect2, varscan2
- ARPP21 | c.1646G>T p.R549I | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV51795406; called by muse, mutect2, varscan2
- ARSA | c.978C>T p.P326= | Splice Region (SNP) | VAF 43/120 reads (36%) | catalogued as rs1405375723, COSV53350406; called by muse, mutect2, varscan2
- ARSD | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.299); catalogued as rs769119418; called by muse, mutect2, varscan2
- ARSH | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.584); catalogued as rs751401251; called by muse, mutect2, varscan2
- ARSL | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as CM137007, COSV66965552; called by muse, mutect2
- ARV1 | c.518del p.K173Sfs*8 | Frame Shift Del (DEL) | VAF 18/53 reads (34%) | catalogued as rs544784472, COSV59618356; called by mutect2, varscan2
- ASAH2 | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 10/197 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.217); catalogued as COSV61484284; called by muse, mutect2
- ASB6 | c.71C>A p.S24Y | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.039); catalogued as COSV52965412; called by muse, mutect2, varscan2
- ASCC3 | c.3200G>A p.R1067Q | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.663); catalogued as rs746929248, COSV61230838; called by muse, mutect2, varscan2
- ASH1L | c.1780G>T p.E594* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as COSV64209485; called by muse, mutect2, varscan2
- ASL | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 59/164 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as rs752397242, CM072868, COSV100509033; called by muse, mutect2, varscan2
- ASL | c.1291G>A p.G431R | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs201733091; called by muse, mutect2, varscan2
- ASNSD1 | c.674T>G p.F225C | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs750362135; called by muse, varscan2
- ASPHD2 | c.146G>A p.G49D | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.601); catalogued as rs369061698, COSV53220899; called by muse, mutect2, varscan2
- ASPM | c.10274C>A p.S3425Y | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.321); catalogued as COSV54127420, COSV54137455, COSV99659149; called by muse, mutect2, varscan2
- ASPM | c.5586G>T p.K1862N | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV54127571; called by mutect2, varscan2
- ASPM | c.2425C>T p.R809C | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751289232, COSV54130333; called by muse, mutect2, varscan2
- ASS1 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.331); catalogued as rs373514077, COSV100752854; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASTN1 | c.3340C>A p.L1114M | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV100707626; called by muse, mutect2, varscan2
- ASTN2 | c.1579G>A p.D527N (on ENST00000313400 / NM_001365069.1; = p.D476N on NM_014010.5) | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as rs976057171, COSV57747261; called by muse, mutect2, varscan2
- ATAD2B | c.1408C>T p.R470* | Nonsense Mutation (SNP) | VAF 19/49 reads (39%) | catalogued as COSV99478116; called by muse, mutect2, varscan2
- ATF5 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756468104, COSV61313288; called by muse, mutect2, varscan2
- ATF7IP | c.3662C>T p.A1221V | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV53778260; called by muse, mutect2, varscan2
- ATG16L1 | c.856C>T p.R286C (on ENST00000392017 / NM_030803.7; = p.R267C on NM_017974.4) | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs755011254, COSV61464356; called by muse, mutect2, varscan2
- ATG4A | c.268C>A p.L90I | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs753988007; called by muse, mutect2, varscan2
- ATIC | c.608A>G p.Q203R | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.98); catalogued as rs1190725980; called by muse, mutect2, varscan2
- ATM | c.7297C>T p.Q2433* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as COSV53756517; called by muse, varscan2
- ATM | c.8356G>A p.G2786S | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs1167044647, COSV53724907; called by muse, mutect2, varscan2
- ATOH1 | c.586T>C p.S196P | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100024523; called by muse, mutect2, varscan2
- ATP10A | c.2249C>T p.S750L | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63513309; called by muse, varscan2
- ATP10B | c.3942C>A p.Y1314* | Nonsense Mutation (SNP) | VAF 7/21 reads (33%) | catalogued as COSV59150759; called by muse, mutect2, varscan2
- ATP10B | c.3408C>A p.F1136L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59150509, COSV59156779; called by muse, varscan2
- ATP10D | c.1848del p.L617Cfs*41 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as rs764067652, COSV56705401; called by mutect2, pindel, varscan2
- ATP11C | c.3181G>A p.A1061T | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.206); catalogued as COSV59567430; called by muse, mutect2, varscan2
- ATP11C | c.1942G>A p.A648T | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV59574720; called by muse, mutect2, varscan2
- ATP13A1 | c.1067C>T p.S356F | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754809322, COSV52290899; called by muse, mutect2, varscan2
- ATP13A3 | c.2764C>T p.P922S | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.439); catalogued as rs773710805; called by muse, mutect2, varscan2
- ATP13A3 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.434); catalogued as rs756090170, COSV55467236; called by muse, mutect2, varscan2
- ATP1A1 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs146195513; called by muse, mutect2, varscan2
- ATP1B2 | c.395G>A p.G132E | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs776106709; called by muse, mutect2, varscan2
- ATP2A1 | c.2632G>A p.E878K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as rs760650232; ClinVar: uncertain significance; called by muse, varscan2
- ATP2A3 | c.2771G>A p.R924Q | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.236); catalogued as rs748838172; called by muse, varscan2
- ATP2A3 | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs766865638, COSV99989718; called by muse, varscan2
- ATP2B1 | c.3355C>T p.R1119* | Nonsense Mutation (SNP) | VAF 11/20 reads (55%) | catalogued as COSV53806099; called by muse, mutect2, varscan2
- ATP2B1 | c.2565C>A p.F855L | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV53807720, COSV53807892; called by muse, mutect2, varscan2
- ATP2B2 | c.3025C>T p.R1009C (on ENST00000352432; = p.R975C on NM_001683.5) | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs768217763; called by muse, mutect2, varscan2
- ATP2B4 | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as rs986432272, COSV100398125; called by muse, mutect2, varscan2
- ATP2B4 | c.1714C>T p.R572C | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762790857, COSV58182692; called by muse, varscan2
- ATP2B4 | c.1795C>T p.R599C | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs765757084, COSV100397940; called by muse, varscan2
- ATP2C1 | c.2630-1G>T p.X877_splice | Splice Site (SNP) | VAF 13/39 reads (33%) | catalogued as CD003709; called by muse, mutect2, varscan2
- ATP2C2 | c.2437G>A p.A813T | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as rs368901898; called by muse, mutect2, varscan2
- ATP6V0A1 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746962618, COSV52872471; called by muse, mutect2, varscan2
- ATP6V0A1 | c.1231G>A p.G411S | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1189944326; called by muse, mutect2, varscan2
- ATP6V0A1 | c.2041G>A p.G681R | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.883); catalogued as rs185595561; called by muse, mutect2, varscan2
- ATP6V1A | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as rs746407800, COSV56361497; called by muse, varscan2
- ATP6V1C2 | c.1177G>A p.A393T (on ENST00000272238 / NM_001039362.2; = p.A347T on NM_144583.4) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.459); catalogued as rs138596209; called by muse, mutect2, varscan2
- ATP8A2 | c.1526C>T p.T509M | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54952522; called by muse, mutect2, varscan2
- ATP8A2 | c.3554C>T p.S1185F | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV54957225; called by muse, mutect2, varscan2
- ATP8B3 | c.3833G>A p.S1278N | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs569828480; called by muse, mutect2, varscan2
- ATP9B | c.294-1G>A p.X98_splice | Splice Site (SNP) | VAF 10/40 reads (25%) | catalogued as rs1235827580; called by muse, mutect2, varscan2
- ATP9B | c.2266C>T p.R756C | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs976628308; called by muse, varscan2
- ATRNL1 | c.931G>T p.V311F | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV61816968; called by muse, mutect2, varscan2
- ATRNL1 | c.4103G>A p.R1368Q | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.921); catalogued as rs782128195, COSV100370029, COSV58079079; called by muse, mutect2, varscan2
- ATRX | c.3518C>T p.S1173L | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs910849788; called by muse, mutect2, varscan2
- ATRX | c.2342G>A p.R781Q | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV64886569; called by muse, mutect2, varscan2
- ATRX | c.1346C>A p.P449H | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as COSV64882486; called by muse, mutect2, varscan2
- ATRX | c.533T>C p.V178A | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as CM1512129; called by muse, mutect2, varscan2
- ATXN7L2 | c.1619C>T p.T540M | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs767353956; called by muse, mutect2, varscan2
- ATXN7L2 | c.1942C>T p.R648W | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.482); catalogued as rs764064522; called by muse, varscan2
- AUP1 | c.1214G>A p.R405Q | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs755850362; called by muse, mutect2, varscan2
- AURKB | c.271G>A p.V91M | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754558313; called by muse, mutect2, varscan2
- AUTS2 | c.1898C>T p.P633L | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs146659460, COSV100717316; called by muse, mutect2, varscan2
- AVIL | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs372626065; called by muse, mutect2, varscan2
- AVPR2 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as rs1216926409; called by muse, mutect2, varscan2
- AWAT2 | c.683C>T p.T228M | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV52143238; called by muse, mutect2, varscan2
- AXIN1 | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as rs1187402204; called by muse, mutect2
- AXIN2 | c.1372G>T p.G458C | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as rs753827256; called by muse, mutect2, varscan2
- B3GAT2 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.929); catalogued as rs755419528, COSV57645254; called by muse, mutect2
- BAG3 | c.1201G>A p.A401T | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1064796532; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAG6 | c.2816G>A p.R939Q (on ENST00000676571; = p.R892Q on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs904232684; called by muse, mutect2, varscan2
- BAIAP2L2 | c.1168G>A p.V390M | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs199751065; called by muse, varscan2
- BAIAP3 | c.2837G>A p.R946H | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as rs116346037; called by muse, mutect2, varscan2
- BANK1 | c.701A>G p.N234S | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1294460649; called by muse, varscan2
- BANK1 | c.763G>T p.E255* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as rs1020905403; called by muse, varscan2
- BANP | c.250G>A p.V84I (on ENST00000286122; = p.V92I on NM_017869.4) | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.946); catalogued as rs1386653214; called by muse, mutect2, varscan2
- BAZ2A | c.1693C>T p.R565C | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51635847; called by muse, mutect2, varscan2
- BAZ2A | c.1657C>T p.R553C | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs759006748, COSV51632239; called by muse, mutect2, varscan2
- BAZ2B | c.4547C>T p.T1516M | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.765); catalogued as rs1444509662, COSV58607797; called by muse, mutect2, varscan2
- BAZ2B | c.4360G>T p.D1454Y | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58599154; called by muse, mutect2, varscan2
- BAZ2B | c.3130C>T p.R1044C | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1406759039; called by muse, mutect2, varscan2
- BAZ2B | c.1313T>G p.F438C | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); catalogued as COSV100600795; called by muse, mutect2, varscan2
- BBOX1 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764375198, COSV54192621; called by muse, mutect2, varscan2
- BBS10 | c.1073C>T p.S358L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as COSV53881041; called by muse, mutect2, varscan2
- BBS12 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.559); catalogued as rs746302850; called by muse, varscan2
- BBS7 | c.1036C>T p.R346W | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs533535422, COSV52659542; called by muse, mutect2, varscan2
- BBS9 | c.2045C>T p.A682V (on ENST00000242067 / NM_001348036.1; = p.A642V on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.087); catalogued as rs1313736607; called by muse, mutect2, varscan2
- BCAN | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1028380044, COSV100228374, COSV61258711; called by muse, mutect2, varscan2
- BCAN | c.2047G>A p.V683I | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV61260086; called by muse, mutect2, varscan2
- BCAS3 | c.1415C>T p.T472M | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs759672810; called by muse, mutect2, varscan2
- BCAS3 | c.2581C>T p.R861* (on ENST00000390652 / NM_001353144.2; = p.R846* on NM_017679.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 12/48 reads (25%) | catalogued as rs1358817701; called by muse, varscan2
- BCCIP | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1189845086; called by muse, mutect2, varscan2
- BCHE | c.897A>T p.E299D | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs948084239; called by muse, mutect2, varscan2
- BCL6 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.342); catalogued as rs372638471, COSV51654854; called by muse, mutect2, varscan2
- BCL9L | c.2884G>A p.V962M | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.804); catalogued as rs1249331698; called by muse, mutect2, varscan2
- BCL9L | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs770108580; called by muse, mutect2, varscan2
- BCLAF1 | c.2551G>A p.D851N | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99219212; called by muse, mutect2, varscan2
- BCLAF1 | c.1249G>A p.A417T | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs761515386, COSV62141141; called by muse, mutect2, varscan2
- BCOR | c.5000C>T p.S1667L (on ENST00000378444 / NM_001123385.2; = p.S1633L on NM_017745.6) | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs754470140, COSV100653358; called by muse, mutect2, varscan2
- BCORL1 | c.5071C>T p.R1691W | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV54411245; called by muse, mutect2, varscan2
- BDH1 | c.973C>T p.R325* | Nonsense Mutation (SNP) | VAF 17/47 reads (36%) | catalogued as rs1354429802, COSV64018000; called by muse, mutect2, varscan2
- BDH1 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs200027383; called by muse, mutect2, varscan2
- BDP1 | c.292A>G p.I98V | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV62430901; called by muse, mutect2, varscan2
- BDP1 | c.5530C>T p.R1844C | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773389976, COSV62429060; called by muse, mutect2, varscan2
- BECN1 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.161); catalogued as rs368727081; called by muse, varscan2
- BEGAIN | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs866787355, COSV100766918; called by muse, mutect2, varscan2
- BICRA | c.2984C>A p.P995H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.923); catalogued as COSV67606117; called by muse, mutect2, varscan2
- BICRAL | c.2186C>T p.A729V | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.071); catalogued as rs1250342735; called by muse, mutect2, varscan2
- BID | c.685C>T p.R229C (on ENST00000317361 / NM_197966.2; = p.R183C on NM_001196.4) | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.664); catalogued as rs538615870; called by muse, mutect2, varscan2
- BIN1 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs764377144; ClinVar: uncertain significance; called by muse, varscan2
- BIN1 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs755355125, COSV52116301; ClinVar: uncertain significance; called by muse, varscan2
- BIRC6 | c.2424G>T p.Q808H | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs745674124; called by muse, mutect2, varscan2
- BLNK | c.1195C>T p.R399* | Nonsense Mutation (SNP) | VAF 25/59 reads (42%) | catalogued as rs1554894837; called by muse, mutect2, varscan2
- BMP1 | c.1486C>T p.R496C | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs200653366; called by muse, mutect2, varscan2
- BMP6 | c.1006+1G>A p.X336_splice | Splice Site (SNP) | VAF 23/56 reads (41%) | catalogued as COSV51664073; called by muse, mutect2, varscan2
- BMP7 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV67779434; called by muse, mutect2, varscan2
- BMPER | c.551G>T p.S184I | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV51817562, COSV51825669; called by muse, mutect2, varscan2
- BMPR1A | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 72/201 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786202611, CM063879, COSV64404982; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BNC2 | c.3232C>T p.R1078* | Nonsense Mutation (SNP) | VAF 23/77 reads (30%) | catalogued as COSV101036129, COSV101036391; called by muse, mutect2, varscan2
- BNC2 | c.1657C>T p.P553S | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.14); catalogued as COSV66141718; called by muse, mutect2, varscan2
- BNC2 | c.484A>G p.I162V | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs760540854; called by muse, mutect2, varscan2
- BPIFB1 | c.906C>A p.F302L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99487291; called by muse, mutect2, varscan2
- BPIFC | c.987G>T p.E329D | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs1376460921; called by muse, mutect2, varscan2
- BPNT2 | c.509C>T p.T170I | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV99389100; called by muse, mutect2, varscan2
- BPTF | c.1976G>A p.G659E | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.927); catalogued as COSV58833835; called by muse, mutect2, varscan2
- BRCA1 | c.5325G>A p.M1775I | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as rs1135401885; ClinVar: not provided / uncertain significance; called by muse, varscan2
- BRCA1 | c.1570G>A p.A524T | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT tolerated (0.23); PolyPhen benign (0.027); catalogued as rs761178502, CD086254, COSV58786854; called by muse, mutect2, varscan2
- BRCC3 | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 56/124 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs782543739; called by muse, mutect2, varscan2
- BRD1 | c.2881G>A p.G961S (on ENST00000216267 / NM_001349940.1; = p.G1092S on NM_001304808.3) | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as rs774876975; called by muse, mutect2, varscan2
- BRD4 | c.2356C>T p.P786S | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs763074040; called by muse, varscan2
- BRD4 | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs867596343, COSV54583236; called by muse, mutect2, varscan2
- BRD9 | c.1265C>T p.A422V | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs778872586, COSV100057298; called by muse, mutect2, varscan2
- BRDT | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.382); catalogued as COSV100746304; called by muse, mutect2, varscan2
- BRDT | c.959G>A p.G320E | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as COSV62863399; called by muse, mutect2, varscan2
- BRICD5 | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as rs149819631; called by muse, mutect2, varscan2
- BRPF3 | c.2134G>A p.E712K | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.198); catalogued as rs774981200; called by muse, mutect2, varscan2
- BRWD3 | c.3445C>T p.R1149W | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64750856; called by muse, mutect2, varscan2
- BRWD3 | c.1594G>T p.D532Y | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100956602; called by muse, mutect2, varscan2
- BSDC1 | c.832G>T p.E278* | Nonsense Mutation (SNP) | VAF 23/82 reads (28%) | catalogued as COSV61983053; called by muse, mutect2, varscan2
- BSN | c.9007C>T p.R3003C | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs755104263, COSV56514392; called by muse, mutect2, varscan2
- BSPRY | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773758644, COSV100949509; called by muse, mutect2, varscan2
- BTAF1 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.223); catalogued as rs753952218, COSV99794759; called by muse, mutect2, varscan2
- BTBD11 | c.2332G>A p.A778T (on ENST00000280758 / NM_001018072.2; = p.A315T on NM_001017523.2) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV99775967; called by muse, mutect2, varscan2
- BTBD16 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 54/137 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs202210822, COSV53260423; called by muse, mutect2, varscan2
- BTG1 | c.415A>G p.N139D | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.87); PolyPhen benign (0.011); catalogued as rs764941738; called by muse, mutect2, varscan2
- BTNL2 | c.1213T>C p.S405P | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.53); catalogued as rs1048174315; called by muse, mutect2, varscan2
- BTRC | c.509C>T p.S170L (on ENST00000370187 / NM_033637.4; = p.S134L on NM_003939.5) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as rs1294863613; called by muse, mutect2, varscan2
- BTRC | c.1009C>T p.R337* (on ENST00000370187 / NM_033637.4; = p.R301* on NM_003939.5) | Nonsense Mutation (SNP) | VAF 21/61 reads (34%) | catalogued as COSV64580833; called by muse, mutect2, varscan2
- BUB1B | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781034323, COSV55014685; called by muse, mutect2, varscan2
- C10orf120 | c.704del p.N235Tfs*7 | Frame Shift Del (DEL) | VAF 17/60 reads (28%) | catalogued as rs775451807; called by mutect2, pindel, varscan2
- C10orf71 | c.1318C>T p.P440S | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.521); catalogued as COSV60509449; called by muse, mutect2, varscan2
- C10orf90 | c.2087G>T p.R696M | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52958635; called by muse, mutect2, varscan2
- C11orf87 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs199870805, COSV59358494; called by muse, mutect2, varscan2
- C12orf42 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.208); catalogued as rs1311532483, COSV59390047; called by muse, mutect2, varscan2
- C12orf50 | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs776851924, COSV53893621; called by muse, mutect2, varscan2
- C12orf66 | c.821A>C p.H274P | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs770905074; called by muse, varscan2
- C14orf119 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs751433100; called by muse, mutect2, varscan2
- C19orf44 | c.1837G>A p.A613T | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as rs1035087822, COSV52222108; called by muse, mutect2
- C1QA | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs1346895142; called by muse, mutect2, varscan2
- C1QB | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs1453569731, COSV100152814; called by muse, mutect2, varscan2
- C1QTNF7 | c.695C>T p.S232L | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs776448155, COSV54856211; called by muse, mutect2, varscan2
- C1R | c.1682G>A p.R561H (on ENST00000536053 / NM_001354346.2; = p.R547H on NM_001733.7) | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.207); catalogued as rs758705788, COSV73383068; called by muse, mutect2, varscan2
- C1orf56 | c.407G>A p.S136N | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.33); catalogued as COSV54848897; called by muse, mutect2, varscan2
- C1orf94 | c.1234C>T p.R412* (on ENST00000488417 / NM_001134734.2; = p.R222* on NM_032884.5) | Nonsense Mutation (SNP) | VAF 31/57 reads (54%) | catalogued as rs775448857, COSV64914334; called by muse, mutect2, varscan2
- C2CD2L | c.1697A>G p.D566G | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763203399; called by muse, mutect2, varscan2
- C2CD3 | c.3691G>A p.V1231I | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as COSV58101598; called by muse, mutect2, varscan2
- C2CD6 | c.1777C>T p.R593* | Nonsense Mutation (SNP) | VAF 29/75 reads (39%) | catalogued as rs748210926, COSV53792214; called by muse, mutect2, varscan2
- C2orf16 | c.1258C>T p.P420S | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.9); PolyPhen benign (0.023); catalogued as COSV68646112; called by muse, mutect2, varscan2
- C2orf16 | c.4375G>A p.D1459N | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.134); catalogued as rs201322374, COSV62677404; called by muse, mutect2, varscan2
- C2orf73 | c.332G>C p.C111S | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as COSV100471411; called by muse, mutect2, varscan2
- C3AR1 | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as rs749041687, COSV50826025; called by muse, mutect2, varscan2
- C3AR1 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs56297048, COSV50820555; called by muse, mutect2, varscan2
- C3orf18 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.469); catalogued as rs200948192; called by muse, mutect2, varscan2
- C4BPA | c.1241C>T p.T414M | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as rs144288941; called by muse, mutect2, varscan2
- C4orf17 | c.914G>T p.R305I | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV99910973; called by muse, mutect2, varscan2
- C4orf19 | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs375131188; called by muse, mutect2, varscan2
- C5 | c.599C>T p.T200M | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as rs767070451, COSV56324677; called by muse, mutect2, varscan2
- C5orf58 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.476); catalogued as COSV99253359; called by muse, mutect2, varscan2
- C6 | c.1853A>G p.N618S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.08); catalogued as rs1381469088; called by muse, varscan2
- C6 | c.1314G>T p.E438D | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54721025; called by muse, mutect2, varscan2
- C6orf15 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs771355605; called by muse, mutect2
- C6orf89 | c.321G>A p.M107I (on ENST00000373685; = p.M114I on NM_152734.4) | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV100769748; called by muse, mutect2, varscan2
- C7orf57 | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs779873173; called by muse, mutect2, varscan2
- C8A | c.80G>A p.R27K | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.967); catalogued as COSV100776661; called by muse, mutect2, varscan2
- C8G | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs553764725, COSV56402987; called by muse, mutect2, varscan2
- C9orf152 | c.356C>T p.T119M | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs780345431; called by muse, mutect2, varscan2
- CA12 | c.239A>G p.N80S | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.587); catalogued as rs1192606278; called by muse, mutect2, varscan2
- CACNA1B | c.5329C>T p.R1777C | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV53120518; called by muse, mutect2, varscan2
- CACNA1C | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.493); catalogued as rs770830796, COSV59700171; called by muse, varscan2
- CACNA1D | c.1385G>A p.R462Q | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs35057005; called by muse, varscan2
- CACNA1D | c.2621C>T p.P874L (on ENST00000350061 / NM_001128840.3; = p.P894L on NM_000720.4) | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.274); catalogued as rs1329283872; called by muse, varscan2
- CACNA1D | c.6418G>A p.E2140K (on ENST00000350061 / NM_001128840.3; = p.E2160K on NM_000720.4) | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.385); catalogued as COSV55453942; called by muse, mutect2, varscan2
- CACNA1E | c.2003G>A p.R668H | Missense Mutation (SNP) | VAF 55/125 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV62384498; called by muse, mutect2, varscan2
- CACNA1E | c.3615G>A p.M1205I | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.444); catalogued as COSV62420617, COSV62432404; called by muse, mutect2
- CACNA1E | c.4755G>T p.K1585N | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV62392082, COSV62406708; called by muse, varscan2
- CACNA1E | c.5795G>A p.R1932Q | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.081); catalogued as rs759385572, COSV100703105; called by muse, mutect2, varscan2
- CACNA1E | c.6799G>A p.G2267S (on ENST00000367573 / NM_001205293.3; = p.G2224S on NM_000721.4) | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1405474687, COSV62405531; called by muse, mutect2, varscan2
- CACNA1F | c.2722G>A p.D908N | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100544898; called by muse, mutect2, varscan2
- CACNA1S | c.5131C>A p.L1711M | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.112); catalogued as COSV100754911; called by muse, mutect2, varscan2
- CACNA1S | c.2794G>A p.V932M | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.992); catalogued as rs373701906; ClinVar: uncertain significance; called by muse, varscan2
- CACNA1S | c.1631C>T p.S544L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs1454338225, COSV62940702; called by muse, mutect2, varscan2
- CACNA1S | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); catalogued as rs370861322; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACTIN | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs551044617, COSV50266721; called by mutect2, varscan2
- CADM1 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.51); PolyPhen benign (0.34); catalogued as rs745679451; called by muse, mutect2, varscan2
- CADPS | c.2332C>T p.R778C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs774579772, COSV51870456, COSV99337363; called by muse, mutect2, varscan2
- CALB2 | c.213C>A p.F71L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.24); catalogued as rs765093163, COSV56940047; called by muse, mutect2
- CALCA | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 58/147 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs782292234, COSV100524130, COSV100524134; called by muse, mutect2, varscan2
- CALCB | c.34C>A p.L12I | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.125); catalogued as COSV100158032; called by muse, mutect2, varscan2
- CALCOCO2 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as rs765125675, COSV104386233, COSV51952812; called by muse, mutect2, varscan2
- CALR | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1208070437; called by muse, mutect2, varscan2
- CALU | c.364G>A p.G122S | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs780108940; called by muse, mutect2, varscan2
- CAMK2D | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.072); catalogued as rs938779568; called by muse, mutect2, varscan2
- CAMK2G | c.1609C>T p.R537C (on ENST00000423381 / NM_001367518.1; = p.R474C on NM_001222.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99990488; called by muse, mutect2, varscan2
- CAMSAP3 | c.3586G>A p.A1196T | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.071); catalogued as rs1393887283, COSV50331606; called by muse, mutect2, varscan2
- CAMTA1 | c.3035G>A p.S1012N | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs934508016; called by muse, mutect2, varscan2
- CAMTA2 | c.2453C>T p.S818L | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.041); catalogued as rs376704366; called by muse, mutect2, varscan2
- CAP2 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs908979234; called by muse, mutect2, varscan2
- CAPN11 | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs755559441; called by muse, mutect2, varscan2
- CAPN3 | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs752483058; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAPN5 | c.1297G>A p.E433K (on ENST00000456580; = p.E393K on NM_004055.5) | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs369845664; called by muse, mutect2, varscan2
- CAPN9 | c.1078C>T p.R360C | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs780436701; called by muse, varscan2
- CAPSL | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 19/60 reads (32%) | catalogued as COSV68438728, COSV68439408; called by muse, mutect2, varscan2
- CARD11 | c.3229C>T p.R1077W | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV67799760; called by muse, varscan2
- CARD11 | c.1222C>T p.R408C | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1053219257, COSV67797339; called by muse, mutect2, varscan2
- CARD14 | c.1356G>T p.E452D | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.108); catalogued as COSV100712629; called by muse, mutect2, varscan2
- CARD6 | c.613G>T p.D205Y | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV54564324; called by muse, mutect2, varscan2
- CARMIL1 | c.2117G>A p.R706Q | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as rs1476173801, COSV61516072; called by muse, mutect2, varscan2
- CARMIL1 | c.3466C>T p.R1156W | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.969); catalogued as rs767321872, COSV61523996; called by muse, mutect2, varscan2
- CARMIL2 | c.518T>C p.F173S | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as rs867927033; called by muse, mutect2, varscan2
- CARMIL2 | c.3332G>A p.R1111Q | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs1249078018, COSV99029526; called by muse, mutect2
- CARNS1 | c.2065G>A p.E689K | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs773007396; called by muse, mutect2, varscan2
- CARS2 | c.1419C>T p.Y473= | Splice Region (SNP) | VAF 34/111 reads (31%) | catalogued as rs568639299, COSV57288157; called by muse, mutect2, varscan2
- CASKIN2 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1471819376, COSV58690016; called by muse, mutect2, varscan2
- CASP14 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs201635146, COSV55665132; called by muse, mutect2, varscan2
- CASP5 | c.923A>G p.K308R | Missense Mutation (SNP) | VAF 59/171 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52829241; called by muse, mutect2, varscan2
- CAST | c.1730G>A p.S577N (on ENST00000341926; = p.S660N on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99701278; called by muse, mutect2
- CAVIN2 | c.827C>T p.T276M | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs551330889, COSV58423947; called by muse, mutect2, varscan2
- CAVIN2 | c.297G>T p.K99N | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV58425250; called by muse, mutect2, varscan2
- CBFA2T3 | c.1697C>T p.T566M | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1274597483; called by muse, mutect2, varscan2
- CBFB | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.15); catalogued as rs761036715, COSV51996734, COSV51999572, COSV52001985; called by muse, mutect2, varscan2
- CBLB | c.1760C>T p.P587L | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.115); catalogued as COSV51434118; called by muse, mutect2, varscan2
- CBLB | c.845G>T p.S282I | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51436804; called by muse, mutect2, varscan2
- CBLN4 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as COSV50353020; called by mutect2, varscan2
- CBX8 | c.538C>T p.R180W | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs533102630; called by muse, mutect2, varscan2
- CCAR2 | c.1267G>A p.V423M | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755104363; called by muse, mutect2, varscan2
- CCAR2 | c.1580G>A p.R527Q | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.799); catalogued as COSV52386508; called by muse, mutect2, varscan2
- CCDC141 | c.2545G>T p.V849F | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV99837178; called by muse, mutect2, varscan2
- CCDC146 | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs148455218, COSV53547020; called by muse, mutect2, varscan2
- CCDC15 | c.999G>T p.Q333H | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as COSV61085399; called by muse, mutect2, varscan2
- CCDC153 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.71); catalogued as COSV59541670; called by muse, mutect2, varscan2
- CCDC173 | c.1297G>T p.D433Y | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as COSV101506385; called by muse, mutect2, varscan2
- CCDC18 | c.2674C>T p.R892* (on ENST00000343253 / NM_001306076.1; = p.R893* on NM_206886.4) | Nonsense Mutation (SNP) | VAF 19/55 reads (35%) | catalogued as rs746890920; called by muse, mutect2, varscan2
- CCDC181 | c.1045A>G p.K349E | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as rs1275618367; called by muse, mutect2
- CCDC185 | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as rs780602669; called by muse, varscan2
- CCDC22 | c.1773C>T p.I591= | Splice Region (SNP) | VAF 39/92 reads (42%) | catalogued as rs1557115183; called by muse, mutect2, varscan2
- CCDC27 | c.1064C>T p.A355V | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as rs1037925937; called by muse, mutect2, varscan2
- CCDC47 | c.628T>C p.S210P | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99853955; called by muse, mutect2, varscan2
- CCDC59 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99810819; called by muse, mutect2, varscan2
- CCDC61 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs1049954005; called by muse, mutect2, varscan2
- CCDC68 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs773758990, COSV61605029; called by muse, mutect2, varscan2
- CCDC7 | c.2336G>T p.R779I | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.122); catalogued as rs780494072, COSV56544548, COSV56548035; called by muse, mutect2, varscan2
- CCDC7 | c.4028C>T p.S1343L | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.988); catalogued as rs761341812, COSV56539494; called by muse, mutect2, varscan2
- CCDC70 | c.512C>T p.T171M | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as rs1434214530; called by muse, mutect2, varscan2
- CCDC80 | c.2684C>T p.S895L | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749914568, COSV52815904; called by muse, mutect2, varscan2
- CCDC86 | c.820C>T p.R274* | Nonsense Mutation (SNP) | VAF 30/62 reads (48%) | catalogued as rs749492752, COSV57126337; called by muse, mutect2, varscan2
- CCDC88A | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1297789580; called by muse, mutect2
- CCDC9 | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.6); PolyPhen benign (0.141); catalogued as rs779041095, COSV55722064; called by muse, mutect2, varscan2
- CCDC96 | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.38); catalogued as COSV59509537; called by muse, mutect2, varscan2
- CCDC96 | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.372); catalogued as COSV59508132; called by muse, mutect2, varscan2
- CCHCR1 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs996478108, COSV66161172; called by muse, varscan2
- CCHCR1 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs149246433; called by muse, varscan2
- CCKAR | c.1085C>T p.S362F | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55160753; called by muse, mutect2, varscan2
- CCL8 | c.257C>A p.S86Y | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1391010219, COSV101126445; called by muse, varscan2
- CCNA1 | c.304A>G p.T102A | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV55223113, COSV99714673; called by muse, mutect2, varscan2
- CCNL2 | c.1048C>A p.L350M | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.771); catalogued as COSV101275766; called by muse, mutect2, varscan2
- CCNL2 | c.335C>T p.T112I | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs370863686; called by muse, varscan2
- CCNL2 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.95); PolyPhen possibly damaging (0.608); catalogued as rs1341660540; called by muse, mutect2, varscan2
- CCPG1 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs750700948; called by muse, varscan2
- CCR2 | c.617G>T p.R206M | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as COSV52748161; called by muse, mutect2, varscan2
- CCR6 | c.890C>T p.T297M | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as rs774906837; called by muse, mutect2, varscan2
- CCT7 | c.1622G>A p.R541H | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs750978474; called by muse, varscan2
- CD151 | c.149G>C p.S50T | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.329); catalogued as rs376496318; called by muse, mutect2, varscan2
- CD163 | c.1750C>T p.R584C | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs373039092; called by muse, mutect2, varscan2
- CD180 | c.1276G>A p.D426N | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1038384169, COSV56516797, COSV56517903; called by muse, mutect2, varscan2
- CD1A | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.221); catalogued as rs763508508, COSV99078803; called by muse, mutect2, varscan2
- CD1C | c.911G>T p.W304L | Missense Mutation (SNP) | VAF 72/191 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63805898; called by muse, mutect2, varscan2
- CD1D | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs755379238; called by muse, mutect2, varscan2
- CD276 | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs747338278; called by muse, mutect2, varscan2
- CD3D | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as rs547344580; called by muse, mutect2, varscan2
- CD40 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs770177808, COSV64848220; called by muse, mutect2, varscan2
- CD53 | c.212G>A p.C71Y | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as COSV54762666; called by muse, mutect2, varscan2
- CD82 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148925723; called by muse, mutect2, varscan2
- CDADC1 | c.1468G>T p.E490* | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as COSV51912808; called by muse, mutect2, varscan2
- CDC123 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs542550865, COSV55396834; called by muse, mutect2, varscan2
- CDC14A | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs190052443, COSV104413708; called by muse, mutect2, varscan2
- CDC26 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs780745708, COSV65252945, COSV65252961; called by muse, mutect2, varscan2
- CDC27 | c.1277G>A p.S426N | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.077); catalogued as rs762807784; called by muse, mutect2, varscan2
- CDC27 | c.388C>T p.R130W | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745491637, COSV50374936; called by muse, mutect2, varscan2
- CDC37 | c.643G>A p.V215I | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs965254505; called by muse, mutect2, varscan2
- CDC42BPB | c.4663C>T p.R1555W | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV100775648; called by muse, mutect2, varscan2
- CDH10 | c.2147A>G p.E716G | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1156402715; called by muse, mutect2, varscan2
- CDH11 | c.352C>T p.R118* | Nonsense Mutation (SNP) | VAF 13/50 reads (26%) | catalogued as COSV51760422; called by muse, mutect2, varscan2
- CDH12 | c.627C>A p.F209L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV101202754, COSV104428502; called by mutect2, varscan2
- CDH15 | c.1222C>T p.Q408* | Nonsense Mutation (SNP) | VAF 36/85 reads (42%) | catalogued as rs1487977733, COSV99228809; called by muse, mutect2, varscan2
- CDH23 | c.4183G>A p.G1395S | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as rs749105554; called by mutect2, varscan2
- CDH3 | c.2059C>T p.L687F | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV50559410; called by muse, mutect2, varscan2
- CDH7 | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV59888974; called by muse, mutect2
- CDH8 | c.1946A>G p.N649S | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV104407990, COSV54860186; called by muse, mutect2, varscan2
- CDH9 | c.2246C>T p.S749L | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1161575895, COSV50265477; called by muse, mutect2, varscan2
- CDH9 | c.976G>T p.E326* | Nonsense Mutation (SNP) | VAF 11/46 reads (24%) | catalogued as COSV50386790; called by muse, mutect2, varscan2
- CDK10 | c.745G>A p.D249N (on ENST00000353379 / NM_052988.5; = p.D178N on NM_052987.4) | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.047); catalogued as rs377692640; called by muse, mutect2, varscan2
- CDK11B | c.1681C>T p.R561C | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1183434157; called by muse, mutect2, varscan2
- CDK15 | c.377G>T p.G126V (on ENST00000652192 / NM_001366386.2; = p.G75V on NM_139158.2) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV53632739; called by muse, mutect2, varscan2
- CDK17 | c.1081C>A p.L361I | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99702785; called by muse, mutect2, varscan2
- CDK17 | c.261G>A p.M87I | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV54126582; called by muse, mutect2, varscan2
- CDK2AP1 | c.167G>A p.S56N | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as rs763372047; called by muse, mutect2, varscan2
- CDKL3 | c.155A>C p.K52T | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1384930916; called by muse, mutect2, varscan2
- CDKN2A | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs1563888782, CM080135, COSV58688371, COSV58714221, COSV58727189; ClinVar: uncertain significance; called by muse, varscan2
- CDON | c.3298G>A p.V1100M | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as rs1221390080; called by muse, mutect2
- CDON | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.37); catalogued as rs761054118, COSV54995637; ClinVar: likely benign; called by muse, varscan2
- CDRT1 | c.1913G>A p.R638Q | Missense Mutation (SNP) | VAF 61/184 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1245706744, COSV63054296; called by muse, mutect2, varscan2
- CDRT1 | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 54/157 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV55411763; called by muse, mutect2, varscan2
- CDRT15 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as rs368683349, COSV69755328; called by muse, varscan2
- CDX1 | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758524697, COSV51568081; called by muse, mutect2, varscan2
- CDX4 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.798); catalogued as rs772299390; called by muse, varscan2
- CDYL2 | c.1390C>T p.R464W | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1346545104, COSV73654985; called by muse, varscan2
- CEACAM18 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.066); catalogued as rs373591127; called by muse, mutect2, varscan2
- CEACAM4 | c.627G>A p.S209= | Splice Region (SNP) | VAF 16/44 reads (36%) | catalogued as rs782042547; called by muse, mutect2, varscan2
- CECR2 | c.781C>T p.R261C (on ENST00000342247 / NM_001290047.2; = p.R98C on NM_001290046.1) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs923281762, COSV52835225; called by muse, mutect2, varscan2
- CECR2 | c.2155C>A p.L719I (on ENST00000342247 / NM_001290047.2; = p.L536I on NM_001290046.1) | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV52846226; called by muse, mutect2, varscan2
- CELF4 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs752918216; called by muse, mutect2, varscan2
- CELSR3 | c.7639G>A p.V2547M | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.068); catalogued as rs752492801; called by muse, mutect2, varscan2
- CEMIP | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs1348692291, COSV55002282; called by muse, mutect2, varscan2
- CEMIP | c.2678G>A p.R893Q | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs778862898, COSV54988859; called by muse, mutect2, varscan2
- CENPA | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs956965320, COSV51982730; called by muse, mutect2
- CENPE | c.8065G>A p.A2689T | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs1039662971; called by muse, mutect2, varscan2
- CENPE | c.1510C>T p.R504C | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV54382015; called by muse, mutect2, varscan2
- CENPF | c.6286G>A p.A2096T | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.843); catalogued as rs371317728, COSV65276365; called by muse, mutect2, varscan2
- CENPJ | c.3823C>T p.R1275C | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as rs1396945698; called by muse, mutect2, varscan2
- CEP104 | c.1193C>T p.P398L | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs751693108; called by muse, mutect2, varscan2
- CEP131 | c.2444G>A p.R815Q (on ENST00000269392 / NM_001319228.2; = p.R812Q on NM_014984.4) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs371928909; called by muse, varscan2
- CEP170 | c.2531C>T p.P844L | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1399144881; called by muse, mutect2, varscan2
- CEP170 | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63732156; called by muse, mutect2, varscan2
- CEP250 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs773605537, COSV61174241; called by muse, mutect2, varscan2
- CEP250 | c.2206C>T p.R736* | Nonsense Mutation (SNP) | VAF 19/50 reads (38%) | catalogued as rs1345217165, COSV61170521; called by muse, mutect2, varscan2
- CEP250 | c.5813G>A p.R1938Q | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs767687865; called by muse, mutect2, varscan2
- CEP290 | c.6283G>T p.D2095Y | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs778771117; called by muse, varscan2
- CEP290 | c.2052T>C p.N684= | Splice Region (SNP) | VAF 11/33 reads (33%) | catalogued as rs1320869248; called by muse, mutect2, varscan2
- CEP350 | c.332C>T p.T111I | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1180290924; called by muse, mutect2, varscan2
- CEP350 | c.3488C>T p.A1163V | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs146703191; called by muse, varscan2
- CEP44 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs368964236; called by muse, mutect2, varscan2
- CEP83 | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.309); catalogued as rs780523565; called by muse, mutect2, varscan2
- CES2 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 82/225 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); catalogued as rs565364625; called by muse, mutect2, varscan2
- CFAP206 | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 20/58 reads (34%) | catalogued as COSV51533981; called by muse, mutect2, varscan2
- CFAP206 | c.628G>T p.D210Y | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV99740050; called by muse, mutect2, varscan2
- CFAP20DC | c.1409C>T p.S470F (on ENST00000482387 / NM_001351530.2; = p.S345F on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV99918615; called by muse, mutect2, varscan2
- CFAP251 | c.3373G>A p.E1125K | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as rs766268774, COSV56613191; called by muse, mutect2, varscan2
- CFAP43 | c.2738G>A p.R913H | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs755312187, COSV99530965; called by muse, mutect2, varscan2
- CFAP44 | c.2223A>C p.E741D | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV99869543; called by muse, mutect2, varscan2
- CFAP44 | c.1622G>A p.R541Q | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs373132679, COSV104404974; called by muse, varscan2
- CFAP47 | c.1523C>A p.S508Y | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.63); PolyPhen benign (0.248); catalogued as COSV99934934; called by muse, mutect2, varscan2
- CFAP47 | c.4369C>T p.Q1457* | Nonsense Mutation (SNP) | VAF 30/104 reads (29%) | catalogued as COSV100544772; called by muse, mutect2, varscan2
- CFAP69 | c.1238C>T p.A413V | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.133); catalogued as rs1418356084; called by muse, mutect2, varscan2
- CFD | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as rs1347153192; called by muse, mutect2, varscan2
- CFH | c.2883A>C p.E961D | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs753657018; called by muse, mutect2, varscan2
- CFHR1 | c.742C>T p.R248* | Nonsense Mutation (SNP) | VAF 19/58 reads (33%) | catalogued as COSV57628191; called by muse, mutect2, varscan2
- CFHR1 | c.941G>A p.R314Q | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.299); catalogued as rs1237921506, COSV57625702, COSV57628365; called by muse, mutect2, varscan2
- CFTR | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs1265244783, CM034780; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHAT | c.1309G>A p.G437S | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs562560467, COSV100340238, COSV60330420; called by muse, mutect2, varscan2
- CHCHD4 | c.32G>A p.R11Q (on ENST00000396914 / NM_001098502.2; = p.R24Q on NM_144636.3) | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs755009391, COSV55499938; called by muse, mutect2, varscan2
- CHD1 | c.2443C>T p.R815W | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753957067; called by muse, mutect2, varscan2
- CHD1 | c.945G>T p.E315D | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.061); catalogued as COSV99399513; called by muse, mutect2, varscan2
11,631 further variants in this file (8,229 protein-altering or splice-affecting, 3,120 silent, 282 other) are not listed here.
